Somatic mutation profile of tumor specimen TCGA-AB-2915-03A (aliquot TCGA-AB-2915-03A-01W-0745-08) from TCGA case TCGA-AB-2915, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 73.8 years (26,968 days).
Specimen TCGA-AB-2915-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 200b2f6f-12e2-45a9-a62e-e8f3dbf562ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2915-11A (Solid Tissue Normal), aliquot TCGA-AB-2915-11A-01W-0745-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b38fcc60-e673-43fb-bfe1-8d0a9a770877

The open-access MAF lists 15 somatic variants for this specimen: 9 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 6, Silent 6, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFAP20DC | c.2236C>T p.R746W (on ENST00000482387 / NM_001351530.2; = p.R495W on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as rs775320019, COSV55921364; called by muse, mutect2, varscan2
- NAA15 | c.773G>A p.W258* | Nonsense Mutation (SNP) | VAF 56/141 reads (40%) | catalogued as rs1283706565, COSV56720207; called by muse, mutect2, varscan2
- NPM1 | c.788A>G p.K263R | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as rs765654691, COSV51561117; called by muse, mutect2, varscan2
- NR2E1 | c.679G>T p.V227F | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV64562081; called by muse, varscan2
- TLE6 | c.1094C>G p.A365G (on ENST00000246112 / NM_001143986.2; = p.A242G on NM_024760.3) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.438); catalogued as COSV55736119, COSV99858108; called by muse, varscan2
- WNK3 | c.1076G>A p.R359Q | Missense Mutation (SNP) | VAF 78/209 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63613987; called by muse, mutect2, varscan2
- ANK2 | c.161dup p.I55Hfs*41 | Frame Shift Ins (INS) | VAF 6/46 reads (13%) | called by mutect2, varscan2
- KRT78 | c.634G>T p.E212* | Nonsense Mutation (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- SLC6A8 | c.1763C>T p.A588V | Missense Mutation (SNP) | VAF 2/8 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2
- DOT1L | c.2328G>C p.P776= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV67110323; called by muse, mutect2, varscan2
- GSTCD | c.15G>A p.K5= | Silent (SNP) | VAF 57/123 reads (46%) | catalogued as COSV64733745; called by muse, mutect2, varscan2
- LILRB1 | c.2085C>T p.Y695= (on ENST00000427581; = p.Y644= on NM_006669.6) | Silent (SNP) | VAF 40/80 reads (50%) | catalogued as rs1395375851, COSV100207047; called by muse, mutect2
- NME9 | c.256C>T p.L86= (on ENST00000333911 / NM_001349024.2; = p.L64= on NM_178130.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as COSV58619224, COSV58621943; called by muse, mutect2, varscan2
- TCEAL1 | c.63G>A p.E21= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV65461129; called by muse, mutect2, varscan2
- TMEM268 | c.501G>A p.L167= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as COSV55986639; called by muse, mutect2, varscan2
